Somatic mutation profile of tumor specimen TARGET-40-0A4I0Q-01A (aliquot TARGET-40-0A4I0Q-01A-01Y) from TARGET case TARGET-40-0A4I0Q, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 19.9 years (7,269 days).
Specimen TARGET-40-0A4I0Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f6a46582-08e5-4cdc-a11c-ecccce020204.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-0A4I0Q-10A (Blood Derived Normal), aliquot TARGET-40-0A4I0Q-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/90730caf-5c60-4450-9fe1-8ca568104057

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Frame Shift Ins 3, RNA 1, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TBX5 | c.1158dup p.S387Qfs*100 | Frame Shift Ins (INS) | VAF 4/30 reads (13%) | catalogued as rs1064795870; ClinVar: likely pathogenic / pathogenic; called by pindel, varscan2
- GLI1 | c.821dup p.C275Lfs*32 | Frame Shift Ins (INS) | VAF 8/40 reads (20%) | catalogued as rs759448855; called by mutect2, varscan2
- LRRIQ4 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV100540137; called by muse, varscan2
- SPDYE1 | c.284dup p.H96Afs*2 | Frame Shift Ins (INS) | VAF 7/48 reads (15%) | catalogued as rs748212274; called by mutect2, varscan2
- TENM4 | c.8153G>A p.R2718Q | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs373894701; called by muse, mutect2, varscan2
- CXXC1 | c.1827G>A p.W609* | Nonsense Mutation (SNP) | VAF 10/13 reads (77%) | called by muse, mutect2, varscan2
- MPZL2 | c.488C>A p.A163E | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- LRRIQ4 | c.711G>A p.S237= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as COSV61618794, COSV61620471; called by muse, mutect2, varscan2
- DHFRP3 | n.40dup | RNA (INS) | VAF 3/18 reads (17%) | called by pindel, varscan2
